Somatic mutation profile of tumor specimen TCGA-BQ-5889-01A (aliquot TCGA-BQ-5889-01A-11D-1589-08) from TCGA case TCGA-BQ-5889, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.7 years (23,267 days).
Specimen TCGA-BQ-5889-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00c66497-16c8-445e-892c-e4c69890e6ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5889-11A (Solid Tissue Normal), aliquot TCGA-BQ-5889-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/076f599d-cbd1-4e20-8efe-8b6fdf8497a6

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Frame Shift Del 2, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.11927T>A p.F3976Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67990536; called by muse, mutect2
- CCT5 | c.1073T>G p.L358R | Missense Mutation (SNP) | VAF 35/349 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV54724786; called by muse, mutect2, varscan2
- CLEC14A | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as COSV60562229; called by muse, mutect2, varscan2
- CRIM1 | c.243C>G p.Y81* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99753300; called by mutect2, varscan2
- DECR2 | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54795481; called by muse, mutect2
- DRD5 | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58579346; called by muse, mutect2, varscan2
- ERCC3 | c.425A>T p.K142M | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53428513; called by muse, mutect2, varscan2
- FAM151A | c.926T>G p.F309C | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56365118; called by muse, mutect2
- FBXO16 | c.175A>C p.T59P | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.127); catalogued as COSV60777046; called by muse, mutect2, varscan2
- FBXO38 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.346); catalogued as rs1032616982, COSV57029546; called by muse, mutect2, varscan2
- FES | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV60999805; called by muse, mutect2
- GLI3 | c.3943C>A p.Q1315K | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as COSV67891722; called by muse, mutect2
- HERC2 | c.1762A>T p.S588C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV55337201; called by muse, mutect2, varscan2
- HYLS1 | c.120G>T p.R40S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV54989305; called by muse, mutect2
- KIFBP | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV62832077; called by muse, mutect2
- MAD1L1 | c.2123C>T p.T708I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360545304, COSV56240852; called by muse, mutect2, varscan2
- MYO1F | c.1658A>C p.K553T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57797797; called by muse, mutect2
- NDUFV1 | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59596050; called by muse, mutect2, varscan2
- NEURL4 | c.4454C>T p.A1485V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as rs1232059236, COSV59751824; called by muse, mutect2
- NOA1 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51737964; called by muse, mutect2
- OTUD4 | c.734G>T p.R245I (on ENST00000447906 / NM_001366057.1; = p.R180I on NM_001102653.1) | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV56851168; called by muse, mutect2
- PDP1 | c.1216T>A p.L406I | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV52602768; called by muse, mutect2
- PHACTR4 | c.1411A>T p.M471L (on ENST00000373839 / NM_001350159.2; = p.M481L on NM_023923.4) | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV65784662; called by muse, mutect2
- PRPF8 | c.4340T>A p.V1447D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV59265495; called by muse, mutect2, varscan2
- SCRN2 | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51636702; called by muse, mutect2, varscan2
- SRBD1 | c.2074A>G p.K692E | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV55402059; called by muse, mutect2, varscan2
- SSX2IP | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV100642684, COSV60553705, COSV60554716; called by muse, mutect2
- STAM | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.867); catalogued as rs782346668, COSV66325640; called by muse, mutect2
- STAM | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.915); catalogued as COSV66325642; called by muse, mutect2
- TEX2 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV51983570; called by muse, mutect2, varscan2
- TMEM62 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as rs1567169181, COSV53042094; called by muse, mutect2
- TNFRSF19 | c.1102A>C p.N368H | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV50316665; called by muse, mutect2
- TSC2 | c.2710T>C p.F904L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV54772605; called by muse, mutect2, varscan2
- TXNIP | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.614); catalogued as COSV65220893; called by muse, mutect2, varscan2
- UBE3B | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV55092537; called by muse, mutect2, varscan2
- UGT1A1 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs375204962, COSV59389396; called by muse, mutect2, varscan2
- YEATS4 | c.284A>C p.E95A | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56089320; called by muse, mutect2, varscan2
- FAM214B | c.1582del p.A528Pfs*99 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, varscan2
- PRPSAP1 | c.1078del p.I360Ffs*47 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- SNX30 | c.173dup p.N58Kfs*24 | Frame Shift Ins (INS) | VAF 26/247 reads (11%) | called by mutect2, pindel, varscan2
- ARAP3 | c.4218A>G p.P1406= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV53352543; called by muse, mutect2, varscan2
- EIF5B | c.843A>T p.V281= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV56815232, COSV56815919; called by muse, mutect2
- EPHB6 | c.756G>T p.G252= | Silent (SNP) | VAF 34/210 reads (16%) | catalogued as COSV67419891; called by muse, mutect2, varscan2
- F8 | c.4182G>A p.T1394= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs782797370, COSV64269894; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPRASP1 | c.1842G>C p.G614= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV64356130; called by muse, mutect2, varscan2
- KCNC2 | c.1818C>A p.G606= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV54363779, COSV54374126; called by muse, mutect2
- NPAP1 | c.2217T>A p.T739= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as COSV61509068; called by muse, mutect2
- PLCXD2 | c.648C>T p.P216= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs372815872; called by muse, mutect2, varscan2
- PYHIN1 | c.876T>G p.A292= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV63723212; called by muse, mutect2
- RFX6 | c.1251T>C p.D417= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as COSV60587209; called by muse, mutect2
- ZP4 | c.171T>A p.A57= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV63912231; called by muse, mutect2
- AGAP7P | n.1200A>C | RNA (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- B4GALNT1 | chr12:57622852 T>C | 3'Flank (SNP) | VAF 14/103 reads (14%) | catalogued as COSV57543827; called by muse, mutect2, varscan2
- OBSCN | c.11660-2674G>A | Intron (SNP) | VAF 12/104 reads (12%) | catalogued as COSV99477250; called by muse, mutect2, varscan2
